TCGA case TCGA-AO-A0JA — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/86b7b206-8e69-432d-acc9-bccce710955e

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 36 years; Vital status: Alive.

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 36.4 years (13,307 days); Year of diagnosis: 2009; Method of diagnosis: Core Biopsy; AJCC pathologic T: T2; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Inner / Breast, Right Lower Inner / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 11; Lymph nodes tested: 11; Micrometastasis present: No.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Initial disease status: Recurrent Disease; Days to treatment start: 166 days; Treatment outcome: Treatment Ongoing; Prescribed dose: 7.5; Prescribed dose units: mg; Route of administration: Intramuscular.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Recurrent Disease; Days to treatment start: 166 days; Days to treatment end: 242 days; Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Bisphosphonate Therapy; Therapeutic agents: Zoledronic Acid; Initial disease status: Recurrent Disease; Days to treatment start: 166 days; Number of cycles: 6; Treatment dose: 24 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 4; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 292 days; Number of cycles: 7; Treatment dose: 980 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 80; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 36.8 years (13,450 days); Days to diagnosis: 143 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 36.8 years (13,450 days); Days to diagnosis: 143 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (3 entries)
- Day 143 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 143 days.
- Days to follow up: 346 days; Disease response: With Tumor.
- Days to follow up: 655 days (1.8 years); Disease response: With Tumor.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ERBB2 (IHC): Negative; Staining intensity value: 1+; Test value range: <10%.
- ESR1 (IHC): Negative; Staining intensity scale: 4 Point Scale.
- ESR1 (IHC): Negative; Test value range: <10%.
- ESR1 (IHC): Positive; Staining intensity value: 2+; Test value range: 90-99%.
- PGR (IHC): Positive; Staining intensity scale: 4 Point Scale; Test value range: 70-79%.
- PGR (IHC): Positive; Staining intensity value: 1+; Test value range: <10%.
- PGR (IHC): Positive; Staining intensity value: 2+; Test value range: 70-79%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AO-A0JA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-AO-A0JA-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 17; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AO-A0JA-01A-01-BSA: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AO-A0JA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AO-A0JA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: No; Er IHC score: 2+; Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Her2 IHC percent positive: <10%; Her2 positivity method text: 3+ POSITIVE; Prospective collection: No; Retrospective collection: Yes; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Inner Quadrant; Anatomic organ subdivision: Right Lower Inner Quadrant; Anatomic organ subdivision: Right.
- Follow-up form 1: Tumor status: With tumor; New tumor event surgery: Yes; New tumor event er status IHC positive: <10%; New tumor event her2 status IHC positive: <10%; New tumor event her2 positivity IHC score: 1+; New tumor event her2 positivity method: 3+ POSITIVE; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Tumor status: With tumor; New tumor event type: Distant Metastasis; New tumor event site: Bone; New tumor event surgery: No; New tumor event her2 positivity IHC score: 1+; New tumor event her2 positivity other scale: 3 Point Scale.
- Drug treatment 1: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: LEUPROLIDE ACETATE (LUPRON); Therapy regimen: Recurrence.
- Drug treatment 2, Route of administrations: Route of administration: IM.
- Drug treatment 4, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 655 days; disease-specific survival: no event (censored), 655 days; disease-free interval: event (new tumor event after initially disease-free), 143 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 143 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AO-A0JA-01A-11D-A059-01): tumor purity 0.66, ploidy 1.79, whole-genome doublings 0.
